Somatic mutation profile of tumor specimen TCGA-KK-A8IF-01A (aliquot TCGA-KK-A8IF-01A-11D-A364-08) from TCGA case TCGA-KK-A8IF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.2 years (20,888 days).
Specimen TCGA-KK-A8IF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5442a6f0-2e9c-483e-a3dc-ada637e46191.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IF-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IF-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d60a77a-e375-4d45-b816-497bff014e74

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 16, Silent 8, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 36/58 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXA1 | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1329067081, COSV51643334, COSV51643414, COSV51644409; called by muse, mutect2, varscan2
- ADAMTS14 | c.2542A>T p.T848S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV100941876; called by muse, mutect2, varscan2
- ATP13A5 | c.2057C>T p.T686I | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100665747; called by muse, mutect2
- BIRC7 | c.865G>A p.V289I (on ENST00000217169 / NM_139317.3; = p.V271I on NM_022161.4) | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs748222291, COSV53901033; called by muse, mutect2, varscan2
- DCHS1 | c.9580C>T p.P3194S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV54998564; called by muse, mutect2
- FBN3 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs753107151, COSV99561880; called by muse, mutect2, varscan2
- FLNC | c.2081C>G p.A694G | Missense Mutation (SNP) | VAF 110/178 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100368767; called by muse, mutect2, varscan2
- HMCN1 | c.3341C>A p.A1114D | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1469535251, COSV99636020; called by muse, mutect2, varscan2
- KMT2C | c.6925C>T p.Q2309* | Nonsense Mutation (SNP) | VAF 50/68 reads (74%) | catalogued as COSV51496341; called by muse, mutect2, varscan2
- OR8D2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100659116, COSV62488870; called by muse, mutect2, varscan2
- SMCHD1 | c.4890G>T p.K1630N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs1274291358, COSV99862625; called by muse, mutect2, varscan2
- SPOP | c.390C>G p.D130E | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100753605; called by muse, mutect2, varscan2
- TCN1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs763549157, COSV99953477; called by muse, mutect2, varscan2
- TNFRSF18 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.077); catalogued as rs761300758, COSV60775632; called by muse, varscan2
- WNK3 | c.4760G>A p.R1587H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201518613, COSV100672149; called by muse, mutect2, varscan2
- ACACA | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TFAP2C | c.762_772del p.E255Cfs*51 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- TYW3 | c.571_573del p.C191del | In Frame Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- ATF7 | c.1227C>T p.C409= (on ENST00000548446 / NM_001366555.2; = p.C398= on NM_006856.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100129793; called by muse, mutect2
- CMIP | c.1887G>A p.L629= (on ENST00000537098 / NM_198390.2; = p.L535= on NM_030629.3) | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as rs1314583512, COSV101220965; called by muse, mutect2
- DYNC2H1 | c.10104C>G p.L3368= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as COSV62089990; called by muse, mutect2, varscan2
- ERICH3 | c.3013C>A p.R1005= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100445851, COSV58614962; called by muse, mutect2, varscan2
- GALNT12 | c.1542T>C p.D514= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100899209; called by muse, mutect2, varscan2
- GFOD1 | c.300C>T p.D100= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs751355135, COSV101015259; called by muse, mutect2, varscan2
- LCP1 | c.1866A>G p.K622= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100550088; called by muse, mutect2
- PANX3 | c.636G>A p.R212= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV99421244; called by muse, mutect2, varscan2
